Gene-level copy-number profile of tumor specimen TCGA-86-8074-01A from TCGA case TCGA-86-8074, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.6 years (22,862 days).
Specimen TCGA-86-8074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.533e6bf0-abc6-42b3-adf8-7db2fdca420a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8074-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26cb094b-ad61-47ef-a1a2-6335068909a6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 947; copy number 2: 1,473; copy number 3: 7,926; copy number 4: 14,903; copy number 5: 14,029; copy number 6: 8,145; copy number 7: 8,769; copy number 8: 991; copy number 9: 107; copy number 10: 106; copy number 12: 142; copy number 13: 682; copy number 14: 228; copy number 15: 772; copy number 16: 315; copy number 18: 19; copy number 19: 237; copy number 21: 14; copy number 24: 7; copy number 36: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8074-01A-11D-2237-01): tumor purity 0.51, ploidy 3.81, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,632 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:105,927,620–107,965,180, 13 genes, copy number 12 (within-gene range 7–12): LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852.
- chr1:116,909,149–156,728,766, 734 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr4:37,821,361–49,062,081, 181 genes, copy number 15 (within-gene range 4–15) (broad region; genes not listed).
- chr4:52,020,706–52,551,574, 4 genes, copy number 16 (within-gene range 3–16): SGCB, LINC02480, SPATA18, AC097522.2.
- chr4:53,377,641–54,295,272, 7 genes, copy number 14 (within-gene range 3–14): FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1.
- chr4:54,603,211–55,092,534, 9 genes, copy number 15: LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P.
- chr5:58,198–45,895,970, 710 genes, copy number 14–16 (within-gene range 2–16) (broad region; genes not listed).
- chr5:100,399,047–101,816,780, 9 genes, copy number 18 (within-gene range 4–18): AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P, OR7H2P.
- chr7:9,082,557–10,239,863, 12 genes, copy number 21: AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3.
- chr7:10,451,311–10,476,878, 2 genes, copy number 21: HSPA8P8, AC009945.1.
- chr7:45,157,791–49,587,165, 56 genes, copy number 19 (within-gene range 8–19): RAMP3, AC073968.2, AC073968.1, ELK1P1, AC073325.1, AC073325.2, ADCY1, SEPTIN7P2, GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, CCDC201, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1.
- chr7:50,093,279–68,319,676, 411 genes, copy number 15–19 (broad region; genes not listed).
- chr11:28,986,635–39,261,213, 147 genes, copy number 10–15 (broad region; genes not listed).
- chr11:72,519,986–74,485,742, 70 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).
- chr11:74,652,636–74,842,413, 8 genes, copy number 15 (within-gene range 3–15): RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169.
- chr11:75,717,838–75,815,406, 7 genes, copy number 13: MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT.
- chr11:75,835,215–75,837,645, 2 genes, copy number 13: Y_RNA, Y_RNA.
- chr11:76,591,023–80,327,911, 69 genes, copy number 16–36 (broad region; genes not listed).
- chr11:80,653,429–82,718,299, 11 genes, copy number 14 (within-gene range 3–14): ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr12:40,692,439–43,789,543, 46 genes, copy number 13 (within-gene range 5–13): CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4.
- chr18:35,443,869–36,279,119, 22 genes, copy number 14: AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3.
- chr18:36,417,055–36,424,185, 1 gene, copy number 14: AC055840.1.
- chr19:27,638,483–32,829,580, 101 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
